Gene-level copy-number profile of tumor specimen TCGA-UF-A7JS-01A from TCGA case TCGA-UF-A7JS, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.3 years (21,676 days).
Specimen TCGA-UF-A7JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cecd4992-090c-449e-9f4b-a087af18af2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a0176ce-6f36-4422-ba01-1b56491a3252

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,356; copy number 3: 350; copy number 4: 41,628; copy number 5: 1,172; copy number 6: 4,850; copy number 7: 334; copy number 8: 1,476; copy number 9: 254; copy number 10: 211; copy number 11: 60; copy number 12: 5; copy number 13: 14; copy number 15: 7; copy number 18: 3; copy number 20: 3; copy number 25: 1; copy number 27: 42; copy number 43: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JS-01A-11D-A34I-01): tumor purity 0.61, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 647 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,516,455–86,861,924, 76 genes, copy number 10 (broad region; genes not listed).
- chr5:710,355–5,078,311, 80 genes, copy number 10–15 (broad region; genes not listed).
- chr5:42,972,624–45,228,428, 45 genes, copy number 10: PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1.
- chr6:121,378,797–122,211,811, 14 genes, copy number 13: Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P.
- chr7:86,643,914–89,496,918, 37 genes, copy number 9: GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1.
- chr8:40,530,590–54,871,720, 217 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:69,048,932–70,436,584, 42 genes, copy number 27: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:101,915,010–103,895,271, 48 genes, copy number 25–43 (within-gene range 2–43): CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1.
- chr11:127,940,913–128,686,922, 7 genes, copy number 12–20: DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1.
- chr11:128,691,672–128,696,023, 1 gene, copy number 12: SENCR.
- chr18:1,509,022–5,004,537, 58 genes, copy number 10 (within-gene range 6–10): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1.
- chr18:74,534,500–75,928,004, 22 genes, copy number 10–18 (within-gene range 2–18): CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1, AC015819.4, AC015819.3, AC015819.5, ZADH2, TSHZ1, AC116003.3, AC116003.1, SMIM21, AC116003.2, AC012101.2, AC012101.1, AC090812.1, AC090338.1, LINC01898, AC021506.1, AC021506.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
